Gene-level copy-number profile of tumor specimen TCGA-G4-6317-01A from TCGA case TCGA-G4-6317, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.5 years (18,822 days).
Specimen TCGA-G4-6317-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.3885a1a0-585e-4c99-9c41-d3ae0981118b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6317-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06a9840e-dae5-4adf-91ac-fa243393c923

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 5,742; copy number 3: 22,295; copy number 4: 19,701; copy number 5: 4,775; copy number 6: 2,037; copy number 7: 2,444; copy number 8: 44; copy number 9: 1,684; copy number 10: 847; copy number 11: 159; copy number 17: 27; copy number 28: 43; copy number 29: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6317-01A-11D-1717-01): tumor purity 0.76, ploidy 3.86, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,829 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9 (broad region; genes not listed).
- chr11:95,963,219–97,086,682, 13 genes, copy number 28: AP000870.1, MAML2, AP000779.1, MIR1260B, CCDC82, JRKL, JRKL-AS1, RNA5SP346, LINC02737, AP003066.1, AP003066.2, MED28P5, AP001836.1.
- chr11:99,020,949–100,358,885, 1 gene, copy number 29 (within-gene range 1–29): CNTN5.
- chr11:100,336,856–100,337,625, 1 gene, copy number 29: RPA2P3.
- chr11:101,129,077–102,727,050, 30 genes, copy number 28 (within-gene range 1–28): PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2, MMP27, MMP8.
- chr17:19,417,769–19,492,991, 1 gene, copy number 17 (within-gene range 2–17): AC004448.2.
- chr17:19,457,080–30,334,059, 335 genes, copy number 9–17 (broad region; genes not listed).
- chr20:3,927,309–4,075,165, 4 genes, copy number 7 (within-gene range 2–7): RNF24, FTLP3, RPL21P2, AL356414.1.
- chr20:5,750,393–7,146,656, 24 genes, copy number 7 (within-gene range 2–7): SHLD1, RNU1-55P, CHGB, KANK1P1, TRMT6, MCM8, AL035461.3, Y_RNA, AL035461.1, MCM8-AS1, AL035461.2, RN7SL498P, CRLS1, LRRN4, AL118505.1, FERMT1, TARDBPP1, AL109618.1, AL109618.2, AL109618.3, CASC20, LINC01713, BMP2, AL096799.1.
- chr20:12,243,308–16,053,197, 33 genes, copy number 7 (within-gene range 6–7): AL109838.1, AL136460.1, PA2G4P2, LINC01722, AL078623.1, AL133331.1, LINC01723, SPTLC3, AL109983.1, ISM1, ISM1-AS1, AL050320.1, AL121782.1, TASP1, GAPDHP2, ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P.
- chr20:15,552,157–16,573,448, 6 genes, copy number 7 (within-gene range 2–7): AL121584.1, ENSAP1, AL079338.1, AL161941.1, PPIAP17, KIF16B.
- chr20:31,257,664–32,439,319, 56 genes, copy number 10: DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B, AL121583.1, ASXL1.
- chr20:32,449,755–32,487,019, 2 genes, copy number 10 (within-gene range 2–10): AL034550.1, AL034550.3.
- chr20:33,675,477–64,313,132, 789 genes, copy number 10 (within-gene range 2–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
